Surgical pathology report (de-identified scan), TCGA case TCGA-13-A5FT, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-13-A5FT-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Carcinoma, serous NOS
8441/3

Site: Ovary, C56.9

SP 4/2/13

Date of Procedure

Specimens Submitted:

- 1: SP: Left adnexal (fs)
- 2: SP: Supracolic omental nodule (fs)
- 3: SP: Enlarged left external iliac lymph node (fs)
- 4: SP: Left cul de sac nodule (fs)
- 5: SP: High left para-aortic lymph node (fs)
- 6: SP: Small bowel nodule
- 7: SP: Additional left IP ligament
- 8: SP: Left pelvic sidewall nodule
- 9: SP: Uterus, cervix, right tube and ovary
- 10: SP: Additional cul-de-sac nodule
- 11: SP: Posterior cul-de-sac biopsy
- 12: SP: Left pelvic biopsy
- 13: SP: Right pelvic biopsy
- 14: SP: Left external iliac lymph node
- 15: SP: Left obturator lymph node
- 16: SP: Right external iliac lymph node
- 17: SP: Right obturator lymph node
- 18: SP: Anterior abdominal wall biopsy
- 19: SP: Left paracolic gutter biopsy
- 20: SP: Left diaphragm biopsy
- 21: SP: Omentum
- 22: SP: Right abdominal adhesion
- 23: SP: Right paracolic gutter biopsy
- 24: SP: Right diaphragm biopsy
- 25: SP: High right para-aortic lymph node
- 26: SP: Left para-aortic lymph node
- 27: SP: Left portacaval lymph node
- 28: SP: Right portacaval lymph node

DIAGNOSIS:

1. LEFT ADNEXA, SALPINGO-OOPHORECTOMY:
- HIGH GRADE SEROUS CARCINOMA OF THE OVARY
- FALLOPIAN TUBE WITH HYDROSALPINX AND CHRONIC SALPINGITIS
- PERIADENXAL LEIOMYOMA

** Continued on next page **

[page 2 of 3]
-
2. SUPRACOLIC OMENTAL NODULE, EXCISION:
- THREE BENIGN LYMPH NODES (0/3)
3. LYMPH NODE, ENLARGED LEFT EXTERNAL ILIAC, EXCISION:
- TWO BENIGN LYMPH NODES (0/2)
4. LEFT CUL DE SAC NODULE, EXCISION:
- HIGH GRADE SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE
5. LYMPH NODE, HIGH LEFT PARA-AORTIC, EXCISION:
- HIGH GRADE SEROUS CARCINOMA INVOLVING ONE LYMPH NODE (1/1)
6. SMALL BOWEL NODULE, EXCISION:
- BENIGN MESOTHELIAL INCLUSION CYST
7. LEFT IP LIGAMENT, ADDITIONAL, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE
8. LEFT PELVIC SIDEWALL NODULE, BIOPSY:
- HIGH GRADE SEROUS CARCINOMA INVOLVING FIBROADIPOSE TISSUE
9. UTERUS, CERVIX, RIGHT TUBE AND OVARY, TOTAL HYSTERECTOMY, RIGHT SALPINGO-OOPHORECTOMY:
- HIGH GRADE SEROUS CARCINOMA INVOLVING OVARY AND FALLOPIAN TUBE
- MYOMETRIUM WITH LEIOMYOMA
- WEAKLY PROLIFERATIVE ENDOMETRIUM
- UNREMARKABLE CERVIX
10. ANTERIOR CUL-DE-SAC NODULE, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1)
11. POSTERIOR CUL-DE-SAC, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE
12. LEFT PELVIC, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE
13. RIGHT PELVIC, BIOPSY:
- BENIGN FIBROADIPSE TISSUE
14. LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION:
- BENIGN FIBROADIPOSE TISSUE; NO LYMPHOID TISSUE IDENTIFIED IN ENTIRELY SUBMITTED SPECIMEN
15. LYMPH NODE, LEFT OBTURATOR, EXCISION:
- FOUR BENIGN LYMPH NODES (0/4)
16. LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1)
17. LYMPH NODE, RIGHT OBTURATOR, EXCISION:
- SIX BENIGN LYMPH NODES (0/6)
18. ANTERIOR ABDOMINAL WALL, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE

** Continued on next page **

[page 3 of 3]
19. LEFT PARACOLIC GUTTER, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE
20. LEFT DIAPHRAGM, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE
21. OMENTUM, RESECTION:
- BENIGN FIBROADIPOSE TISSUE
- TWO BENIGN LYMPH NODES (0/2)
22. RIGHT ABDOMINAL ADHESION, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE
23. RIGHT PARACOLIC GUTTER, BIOPSY:
- BENIGN FIBROADIPOSE TISSUE
24. RIGHT DIAPHRAGM, BIOPSY:
- BENIGN SKELETAL MUSCLE AND FIBROADIPOSE TISSUE
25. LYMPH NODE, HIGH RIGHT PARA-AORTIC, EXCISION:
- FOUR BENIGN LYMPH NODES (0/4)
26. LYMPH NODE, LEFT PARA-AORTIC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1)
27. LYMPH NODE, LEFT PORTACAVAL, EXCISION:
- ONE BENIGN LYMPH NODE (0/1)
28. LYMPH NODE, RIGHT PORTACAVAL, EXCISION:
- TWO BENIGN LYMPH NODES (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Source: NCI Genomic Data Commons file a293548d-fa94-4eb5-b4a5-706482b73773 (TCGA-13-A5FT.B67517DE-A483-4563-8698-51CB95DC5CF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).